Somatic mutation profile of tumor specimen TCGA-DD-A113-01A (aliquot TCGA-DD-A113-01A-11D-A12Z-10) from TCGA case TCGA-DD-A113, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 55.3 years (20,188 days).
Specimen TCGA-DD-A113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 694086e3-30fa-456d-b37f-8190132cd132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A113-10A (Blood Derived Normal), aliquot TCGA-DD-A113-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7709dfc-f5e0-4ca7-82ce-44fb3d74cdb3

The open-access MAF lists 171 somatic variants for this specimen: 125 protein-altering or splice-affecting, 44 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 44, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV58052622; called by muse, mutect2, varscan2
- ADAMTS20 | c.5340T>A p.F1780L | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV67133939; called by muse, mutect2
- ADCY5 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV71901465; called by muse, mutect2, varscan2
- ADCY8 | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as COSV53913174, COSV99654789; called by muse, mutect2, varscan2
- ADGRV1 | c.2110C>A p.P704T | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV67988305; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6928G>A p.G2310R | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV51850871; called by muse, mutect2, varscan2
- AP2B1 | c.63A>T p.E21D | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as COSV52000600; called by muse, mutect2, varscan2
- AQR | c.1158G>T p.L386F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV50038257; called by muse, mutect2, varscan2
- ARHGAP22 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50951363; called by muse, mutect2
- ARL8A | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55343508; called by muse, mutect2
- ATL1 | c.990+2T>A p.X330_splice | Splice Site (SNP) | VAF 43/87 reads (49%) | catalogued as COSV63296753; called by muse, mutect2, varscan2
- ATP13A5 | c.2478G>T p.M826I | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV60871037; called by muse, mutect2
- ATP4A | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52869044; called by muse, mutect2
- ATP6AP1 | c.229T>A p.Y77N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62341067; called by muse, mutect2, varscan2
- BZW1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68419101; called by muse, mutect2, varscan2
- CDK14 | c.155G>T p.C52F (on ENST00000380050 / NM_001287135.2; = p.C34F on NM_012395.3) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV56040215; called by muse, mutect2
- CGAS | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV64808410; called by muse, mutect2, varscan2
- CHPF | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.734); catalogued as rs775706899, COSV60535253; called by muse, mutect2, varscan2
- CLEC1B | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV53725867; called by muse, mutect2
- COL28A1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs752702906, COSV68082891; called by muse, mutect2, varscan2
- COL4A1 | c.4907T>C p.I1636T | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs201012509, COSV65427632; called by muse, mutect2, varscan2
- COL4A5 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 140/518 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as CD961912, COSV60364473; called by muse, mutect2, varscan2
- CRLF1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV66504781; called by muse, mutect2, varscan2
- DCT | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763411727, COSV65467933; called by muse, mutect2, varscan2
- DISP3 | c.972T>G p.D324E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53830240; called by muse, mutect2, varscan2
- DNM3 | c.1674G>C p.W558C (on ENST00000355305 / NM_001350206.2; = p.W548C on NM_015569.5) | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62460908; called by muse, mutect2, varscan2
- DOCK11 | c.3444T>G p.H1148Q | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52241713; called by muse, mutect2
- DUSP8 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as rs571594390, COSV59030561; called by muse, mutect2, varscan2
- FASN | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV60756776; called by muse, mutect2, varscan2
- FAT3 | c.9736C>T p.P3246S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.756); catalogued as COSV53130714; called by muse, mutect2, varscan2
- FBXL19 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.883); catalogued as rs772722567, COSV57943341; called by muse, mutect2, varscan2
- FMNL2 | c.3023T>A p.L1008Q | Missense Mutation (SNP) | VAF 236/463 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.054); catalogued as COSV56497819; called by muse, mutect2, varscan2
- FOXS1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54066605; called by muse, mutect2
- FRS3 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52485355; called by muse, mutect2, varscan2
- FSIP1 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as COSV63225436; called by muse, mutect2, varscan2
- G3BP2 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV62976717; called by muse, mutect2
- GABRA3 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 172/626 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as rs1420749654, COSV64800799; called by muse, varscan2
- GDAP2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 248/323 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763963913, COSV65612787; called by muse, mutect2, varscan2
- HTR2C | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 40/608 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV52215800, COSV99348841; called by muse, mutect2
- HTT | c.7868G>T p.W2623L | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV61864379; called by muse, mutect2, varscan2
- INF2 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs530285485, COSV53033662; called by muse, mutect2, varscan2
- INTS8 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58251431; called by muse, mutect2
- ITPR1 | c.3619C>T p.R1207W (on ENST00000354582; = p.R1192W on NM_002222.7) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56987767; called by muse, mutect2, varscan2
- KANSL3 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 143/273 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV62618731; called by muse, mutect2, varscan2
- KIRREL1 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1324098236, COSV63288375; called by muse, mutect2, varscan2
- LHCGR | c.2030C>G p.T677S | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV54298922; called by muse, mutect2
- LRP1 | c.11318A>G p.E3773G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV54515895; called by muse, mutect2, varscan2
- LYZL1 | c.517C>A p.Q173K (on ENST00000375500; = p.Q127K on NM_032517.6) | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.054); catalogued as COSV64966604; called by muse, mutect2, varscan2
- MAPKBP1 | c.3424G>A p.A1142T (on ENST00000456763 / NM_001128608.2; = p.A1136T on NM_014994.3) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as rs1308417466, COSV52963486; called by muse, mutect2, varscan2
- MCF2L2 | c.472A>C p.K158Q | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV61056206; called by muse, mutect2, varscan2
- MERTK | c.2896G>C p.G966R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV54931285; called by muse, mutect2
- MKRN1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV55437428; called by muse, mutect2, varscan2
- MTMR14 | c.309-1G>A p.X103_splice | Splice Site (SNP) | VAF 36/175 reads (21%) | catalogued as COSV56005730; called by muse, mutect2, varscan2
- MUC16 | c.13168C>T p.Q4390* | Nonsense Mutation (SNP) | VAF 36/389 reads (9%) | catalogued as COSV67475671; called by muse, mutect2
- MYMK | c.623C>A p.P208Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101301148, COSV60601051; called by muse, mutect2, varscan2
- MYO6 | c.2708T>G p.V903G | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV64119639; called by muse, mutect2, varscan2
- MYT1L | c.357T>A p.D119E | Missense Mutation (SNP) | VAF 28/597 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67723453; called by muse, mutect2
- NFIB | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1363394549, COSV66621014; called by muse, mutect2, varscan2
- NOS1 | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57615195; called by muse, mutect2, varscan2
- NOX1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 93/167 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV54195149; called by muse, mutect2, varscan2
- OR10T2 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV57781971; called by muse, mutect2
- OR5D18 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100450900, COSV61737635; called by muse, mutect2
- OR7E24 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.984); catalogued as COSV71702255; called by muse, mutect2
- P3H2 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV60023369; called by muse, mutect2
- PAK5 | c.1838A>T p.E613V | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62030464; called by muse, mutect2, varscan2
- PANX1 | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57134208; called by muse, mutect2
- PATJ | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 75/690 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57165142; called by muse, mutect2, varscan2
- PDS5A | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.726); catalogued as COSV57827414; called by muse, mutect2
- PDX1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66847200; called by muse, mutect2, varscan2
- PGK2 | c.893T>A p.V298D | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs1561922093, COSV59164393; called by muse, mutect2, varscan2
- PLA2G4A | c.2005G>T p.D669Y | Missense Mutation (SNP) | VAF 194/566 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66554845; called by muse, mutect2, varscan2
- PPP1R3A | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV52885444, COSV99492940, COSV99493260; called by muse, mutect2, varscan2
- PPP6R2 | c.1753G>C p.E585Q (on ENST00000216061 / NM_001365836.1; = p.E558Q on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53295162; called by muse, varscan2
- PTGS2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs764607381, COSV66570290; called by muse, mutect2
- RAB32 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as rs1054860397, COSV62249281; called by muse, mutect2, varscan2
- RAG1 | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55026077; called by muse, mutect2, varscan2
- RB1 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 161/218 reads (74%) | catalogued as COSV57297755; called by muse, mutect2, varscan2
- RB1CC1 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1429726848, COSV50254098; called by muse, mutect2
- RHBDL1 | c.649C>T p.R217C (on ENST00000219551 / NM_001318733.2; = p.R152C on NM_001278720.2) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs778300183, COSV53484702; called by muse, mutect2, varscan2
- RNF13 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs138683130; called by muse, mutect2, varscan2
- RNF217 | c.1535G>T p.G512V (on ENST00000521654 / NM_001286398.2; = p.G220V on NM_152553.5) | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51576308; called by muse, mutect2
- RYR2 | c.11111A>T p.D3704V | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV63693069; called by muse, mutect2, varscan2
- SCN3A | c.4643A>G p.D1548G | Missense Mutation (SNP) | VAF 193/387 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV51814236; called by muse, mutect2, varscan2
- SDHAF4 | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65085342; called by muse, mutect2
- SH3GL1 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53658098; called by muse, mutect2, varscan2
- SLC16A6 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as rs782723811, COSV59178015; called by muse, mutect2, varscan2
- SLC25A17 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54351691; called by muse, mutect2, varscan2
- SLC2A5 | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV66237141; called by muse, mutect2, varscan2
- SLC6A4 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs764936225, COSV55567774; called by muse, mutect2
- SMPD4 | c.1174G>A p.A392T (on ENST00000409031 / NM_017951.4; = p.A363T on NM_017751.4) | Missense Mutation (SNP) | VAF 101/455 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs572147978, COSV100302726; called by muse, mutect2, varscan2
- SMTNL1 | c.1340T>G p.V447G (on ENST00000399154; = p.V484G on NM_001105565.2) | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54703227; called by muse, mutect2, varscan2
- SPOP | c.1067T>A p.L356Q | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61654435; called by muse, mutect2, varscan2
- SYCP2 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 307/641 reads (48%) | catalogued as COSV62769452; called by muse, mutect2, varscan2
- SYNE1 | c.16780A>C p.T5594P (on ENST00000367255 / NM_182961.4; = p.T5523P on NM_033071.3) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV55018235; called by muse, mutect2
- SYNJ1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341975632, COSV100448892, COSV59150672; called by muse, mutect2, varscan2
- TASOR | c.1700G>A p.G567D (on ENST00000355628 / NM_001365636.2; = p.G171D on NM_015224.3) | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV62928468; called by muse, mutect2, varscan2
- TCTN3 | c.625A>T p.R209W | Missense Mutation (SNP) | VAF 117/209 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56448598; called by muse, mutect2
- TENM2 | c.4097A>G p.N1366S (on ENST00000518659 / NM_001122679.2; = p.N1127S on NM_001080428.3) | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV69123653; called by muse, mutect2, varscan2
- TMED10 | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV57848028; called by muse, mutect2, varscan2
- TMEM53 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV62407343; called by muse, mutect2, varscan2
- TNIP3 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1370625471, COSV50249651; called by muse, mutect2, varscan2
- TNXB | c.12986T>G p.F4329C (on ENST00000647633; = p.F4082C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/666 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64481412; called by muse, mutect2, varscan2
- TRIM31 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV65059899; called by muse, mutect2, varscan2
- TSPYL5 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV59071946; called by muse, mutect2
- TTN | c.35457T>A p.D11819E (on ENST00000591111; = p.D10892E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/594 reads (5%) | PolyPhen benign (0.001); catalogued as COSV60150822; called by muse, mutect2
- TUBG1 | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52221618; called by muse, mutect2
- TUSC1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as rs1329568788, COSV63661926; called by muse, mutect2, varscan2
- TUT7 | c.3046A>T p.I1016F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52896619; called by muse, mutect2, varscan2
- UBE2J1 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV70561708; called by muse, mutect2, varscan2
- UCKL1 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV62403130; called by muse, mutect2, varscan2
- URM1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.387); catalogued as COSV65717271; called by muse, mutect2
- UTRN | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as COSV62339204; called by muse, mutect2, varscan2
- VAV3 | c.518A>C p.Y173S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58385323; called by muse, mutect2
- WDR31 | c.679C>G p.P227A (on ENST00000374193 / NM_001006615.3; = p.P226A on NM_145241.5) | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV59146684, COSV59147715; called by muse, mutect2, varscan2
- XKR9 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 44/894 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV68773095; called by muse, mutect2
- ZNF253 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as COSV63037615; called by muse, mutect2
- ZNF578 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV69736801; called by muse, mutect2, varscan2
- ZNF69 | c.174G>C p.R58S (on ENST00000429654 / NM_001364730.1; = p.R44S on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 365/638 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV60903879; called by muse, mutect2, varscan2
- ZNF783 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100954293; called by muse, mutect2
- ZNF813 | c.1589A>G p.K530R | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV67176955; called by muse, mutect2
- AHCTF1 | c.3885dup p.C1296Mfs*8 (on ENST00000366508; = p.C1270Mfs*8 on NM_015446.5) | Frame Shift Ins (INS) | VAF 190/801 reads (24%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.878del p.L293Hfs*30 | Frame Shift Del (DEL) | VAF 100/302 reads (33%) | called by mutect2, pindel, varscan2
- MLH3 | c.2987del p.G996Efs*10 | Frame Shift Del (DEL) | VAF 54/260 reads (21%) | called by mutect2, pindel, varscan2
- MYBPH | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- USP42 | c.1440del p.M481Cfs*32 | Frame Shift Del (DEL) | VAF 50/272 reads (18%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3783G>A p.E1261= | Silent (SNP) | VAF 85/224 reads (38%) | catalogued as COSV55293010; called by muse, varscan2
- ADCY2 | c.2313G>A p.V771= | Silent (SNP) | VAF 174/382 reads (46%) | catalogued as rs1420640013, COSV57858581, COSV57880126; called by muse, mutect2, varscan2
- AGBL1 | c.1806A>G p.S602= | Silent (SNP) | VAF 133/240 reads (55%) | catalogued as COSV66862146; called by muse, mutect2, varscan2
- APOB | c.10878T>G p.T3626= | Silent (SNP) | VAF 105/327 reads (32%) | catalogued as rs1359068028, COSV51940819; called by muse, mutect2, varscan2
- ATRNL1 | c.4008T>A p.P1336= | Silent (SNP) | VAF 66/212 reads (31%) | catalogued as COSV58083460, COSV58094756; called by muse, mutect2, varscan2
- BTBD6 | c.888C>T p.G296= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs754243515, COSV59268593, COSV59270209; called by muse, mutect2, varscan2
- CCER1 | c.480G>C p.R160= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV62647280; called by muse, mutect2
- CDH6 | c.612A>G p.G204= | Silent (SNP) | VAF 117/275 reads (43%) | catalogued as COSV54072457; called by muse, mutect2, varscan2
- CNKSR2 | c.1245T>C p.Y415= | Silent (SNP) | VAF 66/344 reads (19%) | catalogued as COSV54259471; called by muse, mutect2
- COPS8 | c.210A>G p.E70= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV62976398; called by muse, mutect2, varscan2
- DGAT1 | c.1437C>T p.L479= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV60048505; called by muse, mutect2, varscan2
- DNAH7 | c.9885G>A p.R3295= | Silent (SNP) | VAF 148/478 reads (31%) | catalogued as COSV56771185; called by muse, mutect2, varscan2
- DOC2A | c.796C>A p.R266= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs370463371, COSV58751816; called by mutect2, varscan2
- EGFLAM | c.843T>A p.P281= | Silent (SNP) | VAF 21/329 reads (6%) | catalogued as COSV59306838; called by muse, mutect2
- EMCN | c.180T>A p.T60= | Silent (SNP) | VAF 48/731 reads (7%) | catalogued as COSV56460431; called by muse, mutect2
- FAM174B | c.309C>A p.T103= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1212959226, COSV59264425; called by muse, mutect2, varscan2
- FAM47B | c.1902C>T p.Y634= | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as COSV61454750; called by muse, mutect2
- FOXG1 | c.732C>A p.R244= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV57397737; called by muse, mutect2, varscan2
- IL9 | c.82C>T p.L28= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV50853545, COSV99192430; called by muse, mutect2, varscan2
- KCNV2 | c.952C>T p.L318= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV66056652; called by muse, mutect2, varscan2
- LAMC1 | c.1455A>G p.E485= | Silent (SNP) | VAF 140/539 reads (26%) | catalogued as rs781326806, COSV51149293; called by muse, mutect2, varscan2
- LTN1 | c.594T>C p.L198= | Silent (SNP) | VAF 78/164 reads (48%) | catalogued as COSV63734152; called by muse, mutect2, varscan2
- MACF1 | c.6714A>T p.T2238= | Silent (SNP) | VAF 155/190 reads (82%) | catalogued as COSV99246429; called by muse, mutect2, varscan2
- MDFIC | c.726T>C p.I242= | Silent (SNP) | VAF 100/251 reads (40%) | catalogued as COSV57564943; called by muse, mutect2, varscan2
- MS4A6A | c.159C>A p.I53= | Silent (SNP) | VAF 74/144 reads (51%) | catalogued as COSV60619733; called by muse, mutect2, varscan2
- MUC16 | c.34086C>A p.P11362= | Silent (SNP) | VAF 22/316 reads (7%) | catalogued as COSV101201304; called by muse, mutect2
- MYH11 | c.315G>A p.L105= | Silent (SNP) | VAF 94/205 reads (46%) | catalogued as COSV55557973; called by muse, mutect2, varscan2
- MYO5B | c.1098G>A p.G366= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV53222244; called by muse, mutect2, varscan2
- NCAM2 | c.486G>A p.R162= | Silent (SNP) | VAF 37/487 reads (8%) | catalogued as COSV53083380; called by muse, mutect2
- NFKBIB | c.246C>A p.A82= | Silent (SNP) | VAF 118/291 reads (41%) | catalogued as COSV58003926; called by muse, mutect2, varscan2
- NFX1 | c.2562G>A p.Q854= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV59310955; called by muse, mutect2, varscan2
- OR8K1 | c.123T>C p.Y41= | Silent (SNP) | VAF 22/343 reads (6%) | catalogued as COSV54403118; called by muse, mutect2
- PAK3 | c.1206T>C p.D402= (on ENST00000262836 / NM_001324328.2; = p.D387= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 219/426 reads (51%) | catalogued as COSV53276378; called by muse, mutect2, varscan2
- PGBD2 | c.1032G>A p.L344= | Silent (SNP) | VAF 82/354 reads (23%) | catalogued as rs769954494, COSV61400506; called by muse, mutect2, varscan2
- POM121L12 | c.855C>T p.L285= | Silent (SNP) | VAF 68/117 reads (58%) | catalogued as COSV68693300; called by muse, mutect2, varscan2
- SH3GL2 | c.360C>A p.A120= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV66051720; called by muse, mutect2, varscan2
- SHANK2 | c.2688G>A p.P896= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs141694314; called by muse, mutect2, varscan2
- SLFN11 | c.1905T>C p.P635= | Silent (SNP) | VAF 27/568 reads (5%) | catalogued as COSV57699309; called by muse, mutect2
- SNX13 | c.2811G>A p.K937= | Silent (SNP) | VAF 38/710 reads (5%) | catalogued as COSV68065842; called by muse, mutect2
- SPDYE5 | c.1005T>C p.R335= | Silent (SNP) | VAF 17/446 reads (4%) | called by muse, mutect2
- SYNE3 | c.1263G>A p.Q421= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV62080375; called by muse, mutect2, varscan2
- TGFBR3 | c.1002T>C p.N334= | Silent (SNP) | VAF 14/209 reads (7%) | catalogued as COSV53027435; called by muse, mutect2
- TMEM267 | c.432T>G p.L144= | Silent (SNP) | VAF 13/210 reads (6%) | catalogued as COSV67992854; called by muse, mutect2
- TMEM79 | c.297A>T p.P99= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as rs553983602, COSV55295872; called by muse, mutect2, varscan2
- AL136982.4 | n.625C>T | RNA (SNP) | VAF 38/1238 reads (3%) | called by muse, mutect2
- TTN | c.10361-4772A>T | Intron (SNP) | VAF 15/388 reads (4%) | called by muse, mutect2
